Somatic mutation profile of tumor specimen TCGA-CM-6167-01A (aliquot TCGA-CM-6167-01A-11D-1650-10) from TCGA case TCGA-CM-6167, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 57.6 years (21,031 days).
Specimen TCGA-CM-6167-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36c15824-8470-4a00-bc6a-1e9f9cf24c95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6167-10A (Blood Derived Normal), aliquot TCGA-CM-6167-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68d20c58-c9a3-44f6-b0b7-55e415928f09

The open-access MAF lists 83 somatic variants for this specimen: 67 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 51, Silent 16, Nonsense Mutation 9, Frame Shift Ins 3, Splice Region 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 13/49 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs55832599, CM120851, COSV52678166, COSV52736883, COSV52827473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.6056C>T p.T2019M | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.157); catalogued as rs372307172; called by muse, mutect2, varscan2
- ACADSB | c.433T>A p.L145I | Missense Mutation (SNP) | VAF 58/408 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as rs1450977477, COSV100715067; called by muse, mutect2, varscan2
- AMER1 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV57659668; called by muse, mutect2, varscan2
- ARHGAP6 | c.2672C>T p.A891V (on ENST00000337414 / NM_013427.3; = p.A688V on NM_013423.3) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV100272227; called by muse, mutect2, varscan2
- BOD1 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 34/508 reads (7%) | catalogued as rs770230247, COSV53632560; called by muse, mutect2
- C16orf89 | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs537472512, COSV60125445; called by muse, mutect2, varscan2
- CA10 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146043972; called by muse, mutect2, varscan2
- CAGE1 | c.1746G>T p.K582N (on ENST00000512086; = p.K446N on NM_205864.3) | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57080152; called by muse, mutect2, varscan2
- CHODL | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV100166580, COSV54732250; called by muse, mutect2, varscan2
- CLUL1 | c.682_683insG p.F228Cfs*7 | Frame Shift Ins (INS) | VAF 35/285 reads (12%) | catalogued as COSV100620894; called by mutect2, pindel, varscan2
- CPEB1 | c.1445C>T p.P482L (on ENST00000617958; = p.P417L on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1321247240, COSV99917379; called by muse, mutect2, varscan2
- CYTH1 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776237586, COSV63120621; called by muse, mutect2, varscan2
- DCLK3 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as rs34416671, COSV101373861; called by muse, mutect2, varscan2
- DHX34 | c.3124G>A p.A1042T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs148368794; called by mutect2, varscan2
- DOCK8 | c.4987A>G p.M1663V | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs779845339, COSV66622572; called by muse, mutect2, varscan2
- DYSF | c.5030G>A p.R1677H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.886); catalogued as rs138472236, COSV50270733; ClinVar: uncertain significance; called by mutect2, varscan2
- ERCC6L2 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 13/137 reads (9%) | catalogued as COSV99998235; called by muse, mutect2
- FFAR3 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs530606489, COSV59909849; called by muse, mutect2, varscan2
- FMR1 | c.688A>T p.M230L | Missense Mutation (SNP) | VAF 103/788 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.645); catalogued as COSV99502920; called by muse, mutect2, varscan2
- GBP1 | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100976213; called by muse, mutect2, varscan2
- GPR179 | c.956G>A p.R319H (on ENST00000621958; = p.R318H on NM_001004334.4) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as rs771821437; called by muse, varscan2
- GRAMD4 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1400246785, COSV100730291; called by muse, mutect2, varscan2
- HMCN1 | c.11932C>T p.R3978* | Nonsense Mutation (SNP) | VAF 84/270 reads (31%) | catalogued as rs999852853, COSV54885466; called by muse, mutect2, varscan2
- HPN | c.15G>A p.E5= | Splice Region (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99384819; called by muse, mutect2, varscan2
- KCNJ14 | c.1192T>A p.C398S | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100287022; called by muse, mutect2, varscan2
- LAMA1 | c.8397G>A p.T2799= | Splice Region (SNP) | VAF 14/84 reads (17%) | catalogued as COSV67543746; called by muse, varscan2
- LATS1 | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1431439182, COSV53589766; called by muse, mutect2
- LYST | c.3125C>G p.A1042G | Missense Mutation (SNP) | VAF 177/494 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV101088066; called by muse, mutect2, varscan2
- MAGEC3 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV71610091; called by muse, mutect2, varscan2
- MAP2 | c.5357C>G p.S1786C | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52308417, COSV99557629; called by muse, mutect2, varscan2
- MARK2 | c.1833G>T p.L611F (on ENST00000402010 / NM_001039469.2; = p.L556F on NM_004954.5) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV100158033; called by muse, mutect2, varscan2
- MCTP2 | c.1525G>A p.G509S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759600196, COSV59151154; called by muse, mutect2, varscan2
- MEFV | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as COSV54826442; called by muse, varscan2
- MICAL2 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 23/141 reads (16%) | catalogued as rs574255304, COSV99816662; called by muse, mutect2, varscan2
- MIOX | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs556477098, COSV99326659; called by muse, mutect2, varscan2
- MSI2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52357211, COSV52367499; called by muse, mutect2
- NID2 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV53497308; called by muse, mutect2, varscan2
- NOTCH1 | c.6284G>A p.R2095H | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs756874994, COSV53101371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2T6 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 29/296 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100861477; called by muse, mutect2, varscan2
- PCDHGA3 | c.317T>A p.I106N | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV99528795; called by muse, mutect2
- PRKCH | c.950C>A p.S317Y | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV60647171, COSV60649626; called by muse, mutect2, varscan2
- RASGEF1C | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.027); catalogued as COSV63183159; called by muse, mutect2, varscan2
- RTF1 | c.631C>A p.R211S | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV101047540, COSV67477990; called by muse, mutect2, varscan2
- RYR2 | c.4678A>C p.I1560L | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.018); catalogued as COSV100767609, COSV100772068; called by muse, mutect2
- SEPSECS | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs774532491, COSV100258642; called by muse, mutect2, varscan2
- SLC17A6 | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV54138948; called by muse, mutect2, varscan2
- SLC5A3 | c.1565C>T p.T522M | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62972106; called by muse, mutect2, varscan2
- SLIT3 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 22/112 reads (20%) | catalogued as rs767508476, COSV60637068; called by muse, mutect2, varscan2
- SUSD5 | c.1130C>T p.T377I | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58880668; called by muse, mutect2, varscan2
- TENM3 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 48/289 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV101304846; called by muse, mutect2, varscan2
- TEX13A | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.192); catalogued as rs782585592, COSV61155370, COSV61178012; called by muse, mutect2, varscan2
- TLR5 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 28/227 reads (12%) | catalogued as rs200942023, COSV60559437; called by muse, mutect2, varscan2
- TMEM183A | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.572); catalogued as COSV100923812, COSV65888032; called by muse, mutect2, varscan2
- TMEM259 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs750855238, COSV99312145; called by muse, varscan2
- TMEM266 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs369743897; called by muse, mutect2, varscan2
- TMEM72 | c.8T>A p.L3H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.569); catalogued as COSV67460980; called by muse, mutect2, varscan2
- TMEM72 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.854); catalogued as rs201160000; called by mutect2, varscan2
- TNXB | c.8086G>A p.D2696N (on ENST00000647633; = p.D2449N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV64485876; called by muse, mutect2
- TWNK | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs572114433, COSV52967532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- YTHDC2 | c.191T>C p.M64T | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99362864; called by muse, mutect2, varscan2
- ZBTB7A | c.1262+1G>A p.X421_splice | Splice Site (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100475329; called by muse, mutect2
- CYLC1 | c.869dup p.N291Efs*7 | Frame Shift Ins (INS) | VAF 78/387 reads (20%) | called by mutect2, pindel, varscan2
- GRIP1 | c.716C>A p.S239* | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- KMT2C | c.14602del p.I4868Lfs*37 | Frame Shift Del (DEL) | VAF 64/259 reads (25%) | called by mutect2, pindel, varscan2
- VNN3 | c.39dup p.A14Cfs*19 | Frame Shift Ins (INS) | VAF 28/252 reads (11%) | called by mutect2, pindel, varscan2
- CDH11 | c.1068G>A p.P356= | Silent (SNP) | VAF 64/278 reads (23%) | catalogued as rs139053832; called by muse, mutect2, varscan2
- CELA2A | c.379C>T p.L127= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs745515252, COSV100657483; called by muse, mutect2, varscan2
- EGFR | c.777G>C p.T259= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV51797542, COSV99286584; called by muse, mutect2, varscan2
- FAT3 | c.13140G>A p.G4380= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV53151132; called by muse, mutect2, varscan2
- HTR1B | c.699A>G p.V233= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs751622735, COSV100885319; called by muse, mutect2, varscan2
- MAML3 | c.3336A>G p.A1112= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV72209768; called by muse, mutect2, varscan2
- MRPL2 | c.750T>A p.V250= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as COSV99537775; called by muse, mutect2, varscan2
- MXRA8 | c.594G>A p.V198= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100491816; called by muse, mutect2, varscan2
- PCDHB7 | c.1023C>T p.N341= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs1554280068, COSV50760872; called by muse, mutect2, varscan2
- PCDHGB6 | c.1344C>T p.N448= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs775680397, COSV53920230; called by muse, mutect2, varscan2
- PDGFRA | c.834C>T p.P278= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as rs770523141, COSV57266992; ClinVar: likely benign; called by muse, mutect2, varscan2
- RNF182 | c.372G>A p.T124= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as rs752410878, COSV70369128; called by muse, mutect2, varscan2
- ST8SIA3 | c.582G>A p.T194= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as rs367988280, COSV60654256; called by muse, mutect2, varscan2
- STK36 | c.3192G>A p.S1064= | Silent (SNP) | VAF 37/374 reads (10%) | catalogued as rs770915285, COSV55325489; called by muse, mutect2, varscan2
- SYNPO | c.1701G>A p.E567= (on ENST00000394243 / NM_001166208.2; = p.E323= on NM_007286.6) | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1407126233, COSV100301836, COSV56938187; called by muse, mutect2, varscan2
- ZIM3 | c.513C>T p.A171= | Silent (SNP) | VAF 30/230 reads (13%) | catalogued as COSV99517611; called by muse, mutect2, varscan2
